CCDI case PBBRPX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/bce03732-e2a8-44b7-b0c7-09c8fce4c0eb

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.1 years (1,116 days).

Biospecimens (3 samples)
- Sample 0DF2DH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DF2DI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DF2DJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
